Somatic mutation profile of tumor specimen TCGA-Z4-A8JB-01A (aliquot TCGA-Z4-A8JB-01A-23D-A37C-09) from TCGA case TCGA-Z4-A8JB, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Aggressive fibromatosis; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 25.0 years (9,123 days).
Specimen TCGA-Z4-A8JB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48da1710-3915-48ee-89ae-24b55cff4322.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Z4-A8JB-10A (Blood Derived Normal), aliquot TCGA-Z4-A8JB-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19af7817-aa11-4147-b055-e6f792dc6c8d

The open-access MAF lists 12 somatic variants for this specimen: 12 protein-altering or splice-affecting.
By variant classification: Missense Mutation 10, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRNL1 | c.3746C>T p.A1249V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100369186; called by muse, mutect2
- LRRC7 | c.1032T>G p.C344W (on ENST00000651989 / NM_001370785.2; = p.C311W on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99227027; called by muse, mutect2, varscan2
- MAP4K1 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67710026; called by muse, mutect2, varscan2
- OR2C3 | c.861C>A p.N287K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100825702; called by muse, mutect2
- OR7D2 | c.859C>G p.P287A | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as COSV100713018; called by muse, mutect2, varscan2
- PPEF1 | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1196325877, COSV100583766; called by muse, mutect2
- SPINT1 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1171746024, COSV59802582; called by muse, mutect2, varscan2
- TNR | c.1686G>C p.Q562H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV99689726; called by muse, mutect2, varscan2
- VPS50 | c.1645C>T p.Q549* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100004832; called by muse, mutect2, varscan2
- ZDHHC6 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as COSV101024398; called by muse, mutect2, varscan2
- ZNF671 | c.1131T>A p.F377L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100235050; called by muse, mutect2, varscan2
- ZNF8 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.961); catalogued as rs1485112198, COSV99544326; called by muse, mutect2
